Somatic mutation profile of tumor specimen TARGET-10-PARFDG-09A (aliquot TARGET-10-PARFDG-09A-01D) from TARGET case TARGET-10-PARFDG, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.6 years (2,765 days).
Specimen TARGET-10-PARFDG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79dc3c92-44ef-4e5b-9f18-05ba432895f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARFDG-10A (Blood Derived Normal), aliquot TARGET-10-PARFDG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b7616c4-d950-47e7-a137-788b82f0c78e

The open-access MAF lists 31 somatic variants for this specimen: 19 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 7, Nonsense Mutation 3, Intron 3, In Frame Del 2, Splice Site 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2508_2510del p.I836del | In Frame Del (DEL) | VAF 16/59 reads (27%) | catalogued as rs121913490; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- CCDC178 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768781343; called by muse, mutect2, varscan2
- CCDC180 | c.1039G>A p.V347I | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs550069242; called by muse, mutect2, varscan2
- FAM205A | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs193234006; called by muse, mutect2, varscan2
- FCGBP | c.2014C>T p.R672* | Nonsense Mutation (SNP) | VAF 54/100 reads (54%) | catalogued as rs751224037; called by muse, mutect2, varscan2
- HHATL | c.1438G>A p.V480I | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.033); catalogued as rs918851737, COSV55132397; called by muse, mutect2, varscan2
- IGHG3 | c.750G>C p.K250N | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as rs754894089; called by muse, mutect2, varscan2
- NEB | c.12245G>A p.R4082H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs781536774, COSV50865917; called by muse, mutect2, varscan2
- OR4K14 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.78); PolyPhen benign (0.006); catalogued as rs751709937, COSV59292230; called by muse, mutect2, varscan2
- OTOP3 | c.1690C>T p.R564C | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs778665286, COSV60912786; called by muse, mutect2
- P3H3 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs782559522; called by muse, mutect2, varscan2
- PAXIP1 | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 6/56 reads (11%) | catalogued as rs910817563, COSV68185098; called by muse, mutect2
- SERPINA5 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); catalogued as COSV100291838; called by muse, mutect2
- SETBP1 | c.2753G>A p.R918Q | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.91); catalogued as rs781033681; called by muse, mutect2, varscan2
- CDH6 | c.524-1G>A p.X175_splice | Splice Site (SNP) | VAF 35/84 reads (42%) | called by muse, mutect2, varscan2
- FBN1 | c.6447T>A p.Y2149* | Nonsense Mutation (SNP) | VAF 10/129 reads (8%) | called by muse, mutect2
- IGHV1-69 | c.337_345del p.Y113_C115del | In Frame Del (DEL) | VAF 5/40 reads (13%) | called by mutect2, pindel*
- NPBWR2 | c.683T>C p.I228T | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- POM121L2 | c.798C>A p.F266L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC168 | c.18642A>G p.K6214= | Silent (SNP) | VAF 5/90 reads (6%) | called by muse, mutect2
- COASY | c.36G>A p.T12= | Silent (SNP) | VAF 19/60 reads (32%) | called by muse, mutect2, varscan2
- ERICH2 | c.387T>C p.D129= | Silent (SNP) | VAF 45/112 reads (40%) | called by muse, mutect2, varscan2
- PLCXD3 | c.723G>A p.S241= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs375308462; called by muse, mutect2, varscan2
- RTL1 | c.1389C>T p.D463= | Silent (SNP) | VAF 45/151 reads (30%) | catalogued as rs966617899, COSV101128303; called by muse, mutect2, varscan2
- SYNE2 | c.585C>T p.C195= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs762405319; called by muse, mutect2
- ZNRF4 | c.681C>A p.G227= | Silent (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- ATG16L2 | c.319-101G>C | Intron (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- OR5AK1P | n.200A>G | RNA (SNP) | VAF 4/66 reads (6%) | called by muse, mutect2
- PER1 | chr17:8156383 G>A | 5'Flank (SNP) | VAF 59/159 reads (37%) | called by muse, mutect2, varscan2
- PTPRN2 | c.2344+5767G>A | Intron (SNP) | VAF 17/39 reads (44%) | catalogued as rs984466879; called by muse, mutect2, varscan2
- SLC2A13 | c.1445+23C>T | Intron (SNP) | VAF 9/43 reads (21%) | catalogued as rs201461644; called by muse, mutect2, varscan2
